Somatic mutation profile of tumor specimen MP2PRT-PASIPX-TMP1-A (aliquot MP2PRT-PASIPX-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASIPX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (739 days).
Specimen MP2PRT-PASIPX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd7f46a9-e697-46a2-a2fb-1a5dee6b4aa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASIPX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASIPX-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32dc735f-48fc-484b-b737-56c1a56d1f26

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/365 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CDR1 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 64/856 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs759631228, COSV65164027; called by muse, mutect2
- MAP2 | c.2637G>T p.L879F | Missense Mutation (SNP) | VAF 34/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52295024; called by muse, mutect2
- PLCB4 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV53821025; called by muse, mutect2
- TBX18 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 39/620 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs139711976; called by muse, mutect2
- GABRA5 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 29/355 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2
- SEC24A | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 53/433 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SLC15A3 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 85/695 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA1 | c.732G>A p.R244= | Silent (SNP) | VAF 52/413 reads (13%) | called by muse, mutect2, varscan2
- GEMIN4 | c.1029C>T p.Y343= | Silent (SNP) | VAF 28/694 reads (4%) | catalogued as rs758088253, COSV56745833; called by muse, mutect2
- OR51V1 | c.492C>A p.I164= | Silent (SNP) | VAF 43/224 reads (19%) | catalogued as COSV58314921, COSV58316349; called by muse, mutect2, varscan2
- PTPRT | c.1203G>T p.R401= | Silent (SNP) | VAF 27/633 reads (4%) | catalogued as COSV100625341; called by muse, mutect2
- TIAM1 | c.2070G>A p.R690= | Silent (SNP) | VAF 99/760 reads (13%) | catalogued as rs1033300659; called by muse, mutect2, varscan2
